Somatic mutation profile of tumor specimen MP2PRT-PARTRD-TMP1-A (aliquot MP2PRT-PARTRD-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARTRD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (713 days).
Specimen MP2PRT-PARTRD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b707abfe-7ee7-4fdd-ad66-2c710f823315.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTRD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTRD-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e453856-98b6-4f8a-be18-b8b39e05e168

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.191); catalogued as rs376430907; called by muse, mutect2, varscan2
- HCN3 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 129/793 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs550961408, COSV64234281; called by muse, mutect2, varscan2
- LMCD1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 68/437 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs553073357, COSV50087243; called by muse, mutect2, varscan2
- PLEKHG5 | c.1073G>A p.R358Q (on ENST00000400915 / NM_001042663.3; = p.R321Q on NM_020631.6) | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs773966438, COSV61704814; called by muse, mutect2, varscan2
- CHD3 | c.5702G>A p.R1901H (on ENST00000330494 / NM_001005273.3; = p.R1867H on NM_005852.4) | Missense Mutation (SNP) | VAF 39/816 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HELLPAR | n.199242del | RNA (DEL) | VAF 11/116 reads (9%) | called by mutect2, pindel, varscan2
